Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A627, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A627-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular
8170/3

Site: Liver, hepatic NOS
C22.0

gn 4/12/13

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Hepatectomy

Tumor size: 7.5 x 7.5 x 7.5 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: CD10+, Hepar+, AFP+

Comments: None

Diagnostic Discrepancy		✓

Source: NCI Genomic Data Commons file 37841983-1ba3-4101-96c3-16863acb449b (TCGA-ED-A627.104D5D1C-E6E3-4806-9E6C-4C949865F713.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).